Gene-level copy-number profile of tumor specimen C3L-08872-03 from CPTAC case C3L-08872, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.6 years (27,265 days).
Specimen C3L-08872-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3c542cb6-4e47-4a8b-a82e-cfea9a04fbfc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08872-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/35ac5c61-dede-4e11-9330-d3f64ae52be0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 565; copy number 2: 56,572; copy number 3: 103; copy number 4: 1,156.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:90,102,271–90,222,851, 6 genes (within-gene range 0–2): FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–2): AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 565. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
